Gene-level copy-number profile of tumor specimen TCGA-2G-AAGY-05A from TCGA case TCGA-2G-AAGY, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Teratoma, benign; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 28.3 years (10,338 days).
Specimen TCGA-2G-AAGY-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.7f432fdf-e162-4241-b8b5-e32e404bee76.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAGY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 390 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ceb84170-6aee-47a7-ae86-218dbe0aba64

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 3,046; copy number 2: 12,420; copy number 3: 29,026; copy number 4: 9,823; copy number 5: 4,600; copy number 6: 342; copy number 7: 755; copy number 8: 93; copy number 10: 125.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAGY-05A-11D-A42X-01): tumor purity 0.79, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.
- chr12:9,480,608–9,576,275, 2 genes: AC092821.1, AC092821.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 973 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 10 (within-gene range 3–10): AC244205.1.
- chr2:88,857,161–89,046,466, 20 genes, copy number 10: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13.
- chr12:66,767–9,658,392, 343 genes, copy number 7 (within-gene range 0–7) (broad region; genes not listed).
- chr12:9,594,551–34,249,958, 505 genes, copy number 7–8 (broad region; genes not listed).
- chr15:20,379,495–22,282,872, 104 genes, copy number 10 (within-gene range 5–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 660. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
